Surgical pathology report (de-identified scan), TCGA case TCGA-06-0241, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Henry Ford Hospital, specimen TCGA-06-0241-01A (Primary Tumor).

[page 1 of 2]
TCGA-06-0241

CLINICAL HISTORY

[REDACTED] has difficulty reading and finding words, and headache. On imaging, she has a 4.0 cm. enhancing tumor in the left inferior and posterior temporal lobe.

OPERATIVE DIAGNOSES

Not Given

Operation/Specimen: A: Brain left temporal tumor, excision biopsy

PATHOLOGICAL DIAGNOSIS:

A. Brain, left temporal, excisional biopsy: Glioblastoma. MIB-1 proliferation index: 13%.
See Comment.

COMMENT

The specimen is fragments of an anaplastic astrocytic proliferation with glial fibrillogenic and undifferentiated areas, microvascular proliferation with necrosis and thrombosis, and zones of tumor necrosis, i.e. a glioblastoma.

INTRA-OPERATIVE CONSULTATION

A. Brain left temporal tumor, touch prep and smears: Glioblastoma. [REDACTED]

GROSS DESCRIPTION

A.
Received fresh, three fragments, 1.0 cm. in aggregate. Soft, diffuent, grey/glistening, very vascular. In total, A1.

MICROSCOPIC DESCRIPTION

[page 2 of 2]
IMMUNOHISTOCHEMISTRY: The GFAP demonstrates fibrillary and soluble positivity in the tumor cells. There are no cells immunoreactive with NeuN, a neuronal marker. A small minority of neoplastic cells expresses mutant p53 protein. With the MIB-1 there is a proliferation index of about 13% in the more active areas.

ICD-9(s):

239.6 239.6

Histo Data

Part A: Brain left temporal tumor, excision biopsy

Taken:	Received:	Block	Ordered	Comment
Stain/cnt				
mGFAP-DA x 1		1		Run NeuN also, please.
Thanks.				
H/E x 1		1		
MIB1-DA x 1		1		
P53DO7 x 1		1		

*** End of Report ***

Source: NCI Genomic Data Commons file e73d3780-dd12-4833-85f5-8bc102af0825 (TCGA-06-0241.32181322-04DC-447D-8121-80E2842E6308.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).